Gene-level copy-number profile of tumor specimen MP2PRT-PAPKMH-TMP1-A from MP2PRT case MP2PRT-PAPKMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (608 days).
Specimen MP2PRT-PAPKMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c7deb0c8-4a6f-41a6-863c-5f6032752369.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPKMH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/f1a2b3b4-011c-4137-91f8-d39ca8cd4fb9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 3,047; copy number 2: 54,131; copy number 3: 1,652.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,277,043, 71 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,714,684–106,771,020, 4 genes: IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
